Somatic mutation profile of tumor specimen TARGET-30-PAPNEP-01A (aliquot TARGET-30-PAPNEP-01A-01W) from TARGET case TARGET-30-PAPNEP, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 2.0 years (720 days).
Specimen TARGET-30-PAPNEP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d4f57cf-c3c0-4bfd-a804-01e38da258f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPNEP-10A (Blood Derived Normal), aliquot TARGET-30-PAPNEP-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/046a68c0-c7ca-4752-884e-79a46be0edad

The open-access MAF lists 24 somatic variants for this specimen: 15 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 8, Nonsense Mutation 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHCTF1 | c.1422G>T p.R474S (on ENST00000366508; = p.R448S on NM_015446.5) | Missense Mutation (SNP) | VAF 100/385 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.036); catalogued as COSV58255091; called by muse, mutect2, varscan2
- ARHGAP45 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV57433217; called by muse, mutect2, varscan2
- CPA5 | c.688A>T p.M230L | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.113); catalogued as COSV62570719; called by muse, mutect2, varscan2
- CRB1 | c.2231G>A p.R744Q | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as rs530046423, COSV66329037; called by muse, mutect2, varscan2
- CTLA4 | c.390G>T p.K130N | Missense Mutation (SNP) | VAF 108/476 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55593181; called by muse, varscan2
- FAM160A2 | c.2857T>A p.L953M (on ENST00000449352 / NM_001098794.2; = p.L967M on NM_032127.4) | Missense Mutation (SNP) | VAF 109/510 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.796); catalogued as COSV56414648; called by muse, mutect2, varscan2
- NEK11 | c.985A>T p.T329S | Missense Mutation (SNP) | VAF 82/383 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV63583828; called by muse, mutect2, varscan2
- NUP160 | c.2257G>A p.G753S | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as COSV65855983; called by muse, mutect2, varscan2
- SFTPC | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.025); catalogued as rs777114058, COSV59346182; called by muse, mutect2, varscan2
- SLC6A20 | c.1238C>A p.A413D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV62072670; called by muse, mutect2
- SUGP2 | c.1577A>T p.E526V | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV58265135; called by muse, mutect2, varscan2
- TKTL2 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 38/133 reads (29%) | catalogued as rs1357215350, COSV54917504; called by muse, mutect2, varscan2
- ZC3H12B | c.1624G>C p.D542H | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59051346; called by muse, mutect2, varscan2
- ZSWIM3 | c.560G>A p.G187D | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54851350; called by muse, mutect2, varscan2
- CEBPZ | c.2657C>A p.S886* | Nonsense Mutation (SNP) | VAF 29/544 reads (5%) | called by muse, mutect2
- CYFIP2 | c.1164G>A p.E388= | Silent (SNP) | VAF 34/406 reads (8%) | called by muse, mutect2
- DRD2 | c.900C>A p.P300= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV60762610; called by muse, mutect2, varscan2
- ITPRID1 | c.2109C>A p.G703= | Silent (SNP) | VAF 30/109 reads (28%) | catalogued as COSV60082302; called by muse, mutect2, varscan2
- OR10H1 | c.900C>T p.V300= | Silent (SNP) | VAF 42/156 reads (27%) | catalogued as rs763196892, COSV58473000; called by muse, varscan2
- OR2H2 | c.834G>A p.V278= | Silent (SNP) | VAF 46/199 reads (23%) | catalogued as COSV63544438; called by muse, mutect2, varscan2
- POMT2 | c.651C>T p.A217= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as rs147845081, COSV55070973; ClinVar: likely benign / uncertain significance; called by mutect2, varscan2
- STAT3 | c.966G>T p.V322= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as COSV52893494; called by muse, mutect2, varscan2
- ZNF711 | c.1357C>A p.R453= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV52158719; called by muse, mutect2, varscan2
- SPRY4 | c.-2C>T | 5'UTR (SNP) | VAF 6/44 reads (14%) | catalogued as rs1181373992; called by muse, mutect2, varscan2
